Somatic mutation profile of tumor specimen TCGA-DU-6392-01A (aliquot TCGA-DU-6392-01A-11D-1705-08) from TCGA case TCGA-DU-6392, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.1 years (12,836 days).
Specimen TCGA-DU-6392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd73a3b5-3461-456a-9d6b-ee583d8d3b9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6392-10A (Blood Derived Normal), aliquot TCGA-DU-6392-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/532d5274-fc66-486e-88f2-2ec6b147bb6c

The open-access MAF lists 12,710 somatic variants for this specimen: 9,401 protein-altering or splice-affecting, 3,062 silent, 247 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,320, Silent 3,062, Nonsense Mutation 584, Splice Site 211, Frame Shift Ins 142, Intron 108, Splice Region 87, RNA 60, Frame Shift Del 43, 3'UTR 37, 5'Flank 18, 3'Flank 12.

Variants (750 of 12,710; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL6 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs104893680, CM042294, CM042295, COSV60116955; ClinVar: pathogenic; called by muse, mutect2
- ASPM | c.9910C>T p.R3304* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as rs587783295, CM142028, COSV54134088; ClinVar: pathogenic; called by muse, varscan2
- ATP7A | c.1933C>T p.R645* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as rs72554640, CM940140; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773001194, CM990305, COSV58820875; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.2722C>T p.R908* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as rs886042153; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEP57 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as rs387906977, CM113693, COSV57689518; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs797044814, CM033762, COSV56585339; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72656387, CM070786; ClinVar: pathogenic; called by muse, mutect2
- CPLANE1 | c.8263dup p.T2755Nfs*8 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs775263897; ClinVar: pathogenic; called by mutect2, varscan2
- CPLANE1 | c.*2776C>T | 3'UTR (SNP) | VAF 23/59 reads (39%) | catalogued as rs749421099, COSV57056397; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CRB1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs62636275, CM040718, CM057655, COSV100958048, COSV66328782, COSV66330317; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHCR7 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs80338853, CM980543; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- DYNC1H1 | c.5884C>T p.R1962C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253881, CM134897, COSV64136205; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERCC4 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147105770, CM101828; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131692059, COSV52798756; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ETFDH | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as rs398124151, CM140874, COSV57015347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ETV6 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs724159946, CM150818, COSV56765799, COSV56766683; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLNA | c.5217G>A p.T1739= (on ENST00000369850 / NM_001110556.2; = p.T1731= on NM_001456.3) | Splice Region (SNP) | VAF 10/33 reads (30%) | catalogued as rs387907371, CS104078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXN1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288977950, CM1211918, COSV56881169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GATAD2B | c.335+1G>A p.X112_splice | Splice Site (SNP) | VAF 40/88 reads (45%) | catalogued as rs1553189681, COSV64085777; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs267606844, CM040424, COSV99247102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLUL | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs80358214, CM057402, CM112872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KAT8 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748699921, COSV54898107; called by muse, mutect2, varscan2
- KCND3 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs786205867, CM124831; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNJ2 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473368, CM070956, COSV54662288; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.39C>T p.G13= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs397517040, COSV55500243, COSV55559231, COSV55756103; ClinVar: likely pathogenic; called by mutect2, varscan2
- KRIT1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as rs886039402, CM022620, COSV60667006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MCCC2 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs886043524, CM010915; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.790+1G>A p.X264_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as rs267607789, CD056182, CS011552, CS1412668, CS982272, COSV51614055; ClinVar: pathogenic; called by muse, mutect2
- MPL | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763568293, CM055993, COSV65244793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs986604359, COSV56739944; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587783841, CM960998, COSV60334236; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs3218716, CM066923, CM950825; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- MYH7 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs3218713, CM910268, COSV62516493; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as rs786203448, CM1413752, COSV100647101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.2965dup p.I989Nfs*5 | Frame Shift Ins (INS) | VAF 24/160 reads (15%) | catalogued as rs797045754; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OXCT1 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121909301, CM005412, COSV52177227; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | hotspot (GDC flag); catalogued as COSV56262126; called by muse, mutect2, varscan2
- PEX10 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as rs61750434, CM981515; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PHEX | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as rs866429868, CM971158, COSV65078245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHKA2 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs1556007472, CM981534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLEKHG5 | c.1191+1G>A p.X397_splice (on ENST00000400915 / NM_001042663.3; = p.X360_splice on NM_020631.6) | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as rs1553174500; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTPN11 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs397507541, CM041072, COSV61005566; ClinVar: pathogenic; called by muse, varscan2
- RAD50 | c.3229C>T p.R1077* | Nonsense Mutation (SNP) | VAF 98/297 reads (33%) | catalogued as rs368980595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RERE | c.248dup p.S84Vfs*4 | Frame Shift Ins (INS) | VAF 123/344 reads (36%) | catalogued as rs1557461427; ClinVar: pathogenic; called by mutect2, varscan2
- RET | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779996040; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLTM | c.2600C>A p.P867H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs1401798992; ClinVar: likely pathogenic; called by muse, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2
- TFG | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 52/110 reads (47%) | catalogued as rs764959531, COSV53749011; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 19/81 reads (23%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- TRPV3 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517884, CM1512255, CM1512256, COSV100028194; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.78181C>T p.R26061* (on ENST00000591111; = p.R18637* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 72/168 reads (43%) | catalogued as rs1559314812, COSV59879573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.76114C>T p.R25372* (on ENST00000591111; = p.R17948* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 45/130 reads (35%) | catalogued as rs869038795, CM1413533, COSV59999995; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.45373C>T p.R15125* (on ENST00000591111; = p.R7701* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs754866489, COSV59917424; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 40/116 reads (34%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as rs587784571, CM041103, COSV100355710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99255634; called by muse, mutect2, varscan2
- A2ML1 | c.3427A>G p.I1143V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1469715388; called by mutect2, varscan2
- AADACL4 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs200551069; called by muse, mutect2, varscan2
- ABCA1 | c.3245G>A p.R1082H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761945307, COSV66065412; called by muse, mutect2, varscan2
- ABCA12 | c.6392C>A p.P2131Q (on ENST00000272895 / NM_173076.3; = p.P1813Q on NM_015657.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99788485; called by muse, mutect2
- ABCA13 | c.5769G>T p.K1923N | Missense Mutation (SNP) | VAF 80/244 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV70026891; called by muse, mutect2, varscan2
- ABCA13 | c.14949G>T p.Q4983H | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV101291233, COSV68944672; called by muse, mutect2, varscan2
- ABCA2 | c.3391C>T p.R1131C (on ENST00000614293; = p.R1101C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs771747170; called by muse, varscan2
- ABCA3 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368830525; called by muse, varscan2
- ABCA4 | c.4204G>A p.A1402T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs554101094, COSV64672517; called by muse, mutect2, varscan2
- ABCA9 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100383497; called by muse, mutect2, varscan2
- ABCB1 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99711755; called by muse, mutect2, varscan2
- ABCB5 | c.502A>C p.T168P | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV51722326; called by mutect2, varscan2
- ABCB5 | c.3002G>A p.R1001H (on ENST00000404938 / NM_001163941.2; = p.R556H on NM_178559.6) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs528761902, COSV51716155; called by muse, mutect2, varscan2
- ABCB8 | c.1753G>A p.A585T (on ENST00000297504 / NM_001282291.2; = p.A568T on NM_007188.5) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs889958098; called by muse, varscan2
- ABCC1 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.452); catalogued as rs768562502, COSV60684547; called by muse, mutect2, varscan2
- ABCC1 | c.3490G>A p.V1164I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs202134920; called by muse, mutect2, varscan2
- ABCC10 | c.2236C>A p.L746I (on ENST00000372530 / NM_001198934.2; = p.L718I on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as rs1413286363; called by muse, mutect2, varscan2
- ABCC10 | c.4123C>A p.L1375M (on ENST00000372530 / NM_001198934.2; = p.L1347M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV55093143; called by muse, mutect2, varscan2
- ABCC12 | c.3094C>T p.L1032F | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs1479839394, COSV60916395; called by muse, mutect2, varscan2
- ABCC3 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376917479; called by muse, mutect2, varscan2
- ABCC3 | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as rs746171655, COSV99559140; called by muse, mutect2, varscan2
- ABCC4 | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs925622427; called by muse, mutect2, varscan2
- ABCC5 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as rs371992489; called by muse, mutect2, varscan2
- ABCC6 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs557180313, COSV52743539; called by muse, mutect2, varscan2
- ABCC8 | c.1808C>A p.A603D | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56855671; called by muse, mutect2, varscan2
- ABCC9 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV53980395; called by muse, mutect2, varscan2
- ABCD1 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs782611445; called by muse, varscan2
- ABCF2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as rs1563618730, COSV55185714; called by muse, mutect2, varscan2
- ABCG5 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs148186696; ClinVar: uncertain significance; called by muse, varscan2
- ABCG8 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); catalogued as CX044199; called by muse, mutect2, varscan2
- ABCG8 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs766212636, CM012312, COSV55390446, COSV55393699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABL1 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 67/151 reads (44%) | catalogued as COSV59340385; called by muse, mutect2, varscan2
- ABL1 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1456042173, COSV59334185; called by muse, mutect2, varscan2
- ABLIM3 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs1401146462; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1121C>A p.T374N | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.06); catalogued as COSV99788460; called by muse, varscan2
- ABTB2 | c.2857G>A p.V953M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539287676, COSV54395735; called by muse, mutect2, varscan2
- ABTB2 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs771403049; called by muse, mutect2, varscan2
- AC005833.1 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious, low confidence (0); catalogued as rs1255124759; called by muse, mutect2, varscan2
- AC006059.2 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as rs1036743889, COSV59607187; called by muse, mutect2
- AC008763.3 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs1568483015; called by muse, mutect2, varscan2
- AC011455.2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC011462.1 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1191782907, COSV99524708; called by muse, mutect2
- ACAA2 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771012528, COSV53270631; called by muse, mutect2, varscan2
- ACAD10 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs544200576, COSV58163103; called by muse, varscan2
- ACAD11 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1280388781, COSV53894653; called by muse, mutect2, varscan2
- ACAD8 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1347584475; called by muse, mutect2, varscan2
- ACADM | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as CM042922; called by muse, mutect2, varscan2
- ACCSL | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as rs746976918, COSV66580653; called by muse, varscan2
- ACD | c.1405C>T p.R469W (on ENST00000620338; = p.R380W on NM_022914.3) | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747913250, COSV54667057; called by muse, mutect2, varscan2
- ACER1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.264); catalogued as rs368764098; called by muse, mutect2, varscan2
- ACER1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as rs750798319; called by muse, varscan2
- ACHE | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1184894993, COSV53815900; called by muse, mutect2, varscan2
- ACKR2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56176699; called by muse, mutect2, varscan2
- ACKR3 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs764138712, COSV56021529; called by muse, varscan2
- ACLY | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1555632264; called by muse, mutect2, varscan2
- ACO2 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as rs1389336695, COSV53440878; called by muse, mutect2, varscan2
- ACOT1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs375253960, COSV58570851; called by mutect2, varscan2
- ACOT11 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.68); catalogued as COSV100650690; called by muse, mutect2
- ACOX1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs772711900; called by muse, mutect2, varscan2
- ACOX3 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs373776313; called by muse, mutect2, varscan2
- ACSBG1 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as rs753613833; called by muse, mutect2, varscan2
- ACSBG2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs868360772; called by muse, mutect2, varscan2
- ACSL3 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62484728; called by muse, mutect2, varscan2
- ACSM3 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs773261352, COSV99184976; called by muse, mutect2, varscan2
- ACSS2 | c.710G>A p.C237Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1419950372; called by muse, varscan2
- ACSS2 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767366802, COSV53626985; called by muse, mutect2, varscan2
- ACTL10 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1176507854; called by muse, mutect2, varscan2
- ACTL7B | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs1445853644, COSV65927012, COSV65927740; called by muse, mutect2, varscan2
- ACTN2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV100856699; called by muse, varscan2
- ACTN2 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs368040932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR10 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs199506195, COSV54299107; called by muse, mutect2, varscan2
- ACTR8 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as rs772449859; called by muse, varscan2
- ACTRT2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs753334145; called by muse, varscan2
- ACVR1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs554387941, COSV55117794; called by muse, mutect2, varscan2
- ACVR1B | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs757077272, COSV99232295; called by muse, mutect2, varscan2
- ACVRL1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs746430008; called by muse, mutect2, varscan2
- ADA2 | c.961G>T p.G321W (on ENST00000262607; = p.G80W on NM_177405.3) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52830738; called by muse, mutect2, varscan2
- ADAD1 | c.244dup p.I82Nfs*3 | Frame Shift Ins (INS) | VAF 30/74 reads (41%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAD2 | c.793G>A p.G265S (on ENST00000315906 / NM_001145400.2; = p.G347S on NM_139174.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777675580; called by muse, varscan2
- ADAM15 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs895501050, COSV55127413; called by muse, mutect2, varscan2
- ADAM18 | c.1097G>T p.R366I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV55847024, COSV55853980; called by muse, mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAM33 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376187665; called by mutect2, varscan2
- ADAM8 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs765162641; called by muse, mutect2, varscan2
- ADAMDEC1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs1300666588; called by muse, mutect2, varscan2
- ADAMDEC1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as rs767110341; called by muse, varscan2
- ADAMTS10 | c.619T>C p.W207R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1555741512; called by muse, mutect2, varscan2
- ADAMTS13 | c.4081C>T p.R1361W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1345844859; called by muse, mutect2, varscan2
- ADAMTS2 | c.2101G>A p.G701S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs755490840; called by muse, mutect2, varscan2
- ADAMTS7 | c.2519-1G>T p.X840_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV66307667; called by muse, mutect2
- ADAMTS9 | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1049047605, COSV55776682; called by muse, mutect2, varscan2
- ADAMTSL1 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV99443921; called by muse, mutect2
- ADAMTSL1 | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1000877408, COSV52810690; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1563790470; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4615G>A p.A1539T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.287); catalogued as rs775059724, COSV65876728, COSV65878684; called by muse, mutect2, varscan2
- ADAMTSL2 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751365777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54446119; called by muse, varscan2
- ADAMTSL3 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs139144597; called by mutect2, varscan2
- ADAMTSL3 | c.3772C>T p.Q1258* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as rs760147184; called by mutect2, varscan2
- ADAMTSL4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.17); catalogued as rs777463641; called by muse, varscan2
- ADAMTSL4 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs752465710, COSV54996148; called by muse, mutect2, varscan2
- ADCK1 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.185); catalogued as COSV53087195; called by muse, varscan2
- ADCK1 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs140287525; called by muse, mutect2, varscan2
- ADCK5 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782000623; called by muse, mutect2, varscan2
- ADCY10 | c.4751T>G p.I1584S | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV63244838; called by muse, mutect2, varscan2
- ADCY10 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100897110; called by muse, mutect2, varscan2
- ADCY10 | c.1346T>G p.V449G | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as COSV63240463; called by muse, mutect2, varscan2
- ADCY10 | c.697T>C p.C233R | Missense Mutation (SNP) | VAF 29/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1247029697; called by muse, mutect2
- ADCY2 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs573846891, COSV57890528, COSV57906803; called by muse, mutect2, varscan2
- ADCY3 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs754065461; called by muse, varscan2
- ADCY5 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781491004, COSV59203669; called by muse, mutect2
- ADCY9 | c.2638G>A p.V880I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs377240633; called by muse, varscan2
- ADD2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as rs1327135861, COSV100036769, COSV52464540; called by muse, mutect2, varscan2
- ADD2 | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52468357; called by muse, mutect2, varscan2
- ADGRB1 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as rs751928873; called by muse, mutect2, varscan2
- ADGRD1 | c.2041G>T p.G681C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750891285; called by muse, mutect2, varscan2
- ADGRF1 | c.2438A>G p.D813G | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as rs374690250; called by muse, mutect2, varscan2
- ADGRF3 | c.1804G>A p.A602T (on ENST00000311519 / NM_001145168.1; = p.A403T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs147071305; called by mutect2, varscan2
- ADGRF5 | c.3374C>T p.S1125F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51941004; called by muse, mutect2, varscan2
- ADGRG7 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56301012; called by muse, mutect2, varscan2
- ADGRL1 | c.3880C>T p.R1294W (on ENST00000340736 / NM_001008701.3; = p.R1289W on NM_014921.5) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746407235, COSV100529547, COSV61565126; called by muse, mutect2, varscan2
- ADGRL2 | c.1996G>A p.E666K (on ENST00000370717 / NM_001366005.1; = p.E653K on NM_012302.4) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV54665268; called by muse, mutect2, varscan2
- ADGRV1 | c.7382C>T p.P2461L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs560465803; called by muse, mutect2, varscan2
- ADGRV1 | c.11722G>A p.D3908N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as rs749544658, COSV101316185, COSV67979351; called by muse, mutect2, varscan2
- ADGRV1 | c.15925G>A p.E5309K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1178215841, COSV67997261; called by muse, mutect2
- ADIRF | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV64394305; called by muse, mutect2, varscan2
- ADM5 | c.14T>A p.I5N | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs375061308; called by muse, mutect2, varscan2
- ADNP2 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV51538661; called by muse, mutect2, varscan2
- ADORA3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs746154553, COSV53987170; called by muse, mutect2, varscan2
- ADPGK | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.481); catalogued as rs1403512597; called by muse, mutect2, varscan2
- ADPRH | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189558030; called by muse, mutect2, varscan2
- ADPRHL1 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776092773; called by muse, mutect2, varscan2
- ADRA1B | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs187500825; called by muse, mutect2, varscan2
- AFDN | c.4007C>T p.T1336I | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); catalogued as rs1416249148; called by muse, varscan2
- AFF3 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.408); catalogued as rs747342267, COSV99079726; called by muse, varscan2
- AFF4 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs771044846, COSV99534515; called by muse, mutect2, varscan2
- AFG3L2 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV52312727; called by muse, mutect2, varscan2
- AFM | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs149614377, COSV56919959; called by muse, mutect2, varscan2
- AGBL2 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs1429068909; called by muse, varscan2
- AGBL5 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV104403741; called by muse, mutect2, varscan2
- AGBL5 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs761283059; called by mutect2, varscan2
- AGO1 | c.1331T>C p.I444T | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.069); catalogued as rs1313546401; called by muse, mutect2, varscan2
- AGPAT5 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as rs778146027; called by mutect2, varscan2
- AGPS | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1385845465; called by muse, mutect2, varscan2
- AGRN | c.5200C>T p.R1734C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372565629, COSV65068404; ClinVar: uncertain significance; called by muse, varscan2
- AGT | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.034); catalogued as COSV100794163; called by muse, mutect2, varscan2
- AGTPBP1 | c.1358G>A p.R453H (on ENST00000357081 / NM_001330701.2; = p.R413H on NM_015239.2) | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.361); catalogued as rs1457551466, COSV61271241; called by muse, mutect2, varscan2
- AGXT | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs574507041; called by muse, varscan2
- AGXT2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1277088019; called by muse, mutect2, varscan2
- AHCTF1 | c.2239C>T p.R747C (on ENST00000366508; = p.R721C on NM_015446.5) | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs1434456460; called by muse, mutect2, varscan2
- AHDC1 | c.3299G>A p.R1100Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs201371526; called by muse, mutect2, varscan2
- AHDC1 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as rs952240561; called by muse, mutect2, varscan2
- AHDC1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs758829967, COSV55940949; called by muse, mutect2, varscan2
- AHNAK | c.17142G>A p.M5714I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs769993431; called by muse, mutect2, varscan2
- AHNAK | c.12570A>C p.K4190N | Missense Mutation (SNP) | VAF 131/299 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57208820; called by muse, mutect2, varscan2
- AHNAK | c.6943C>T p.P2315S | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs777241071; called by muse, mutect2, varscan2
- AHNAK2 | c.12038C>T p.A4013V | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs779239371; called by muse, mutect2, varscan2
- AHNAK2 | c.10457C>T p.S3486L | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as rs777676247; called by muse, varscan2
- AHRR | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs775797513; called by muse, mutect2, varscan2
- AHSP | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749437341; called by muse, mutect2, varscan2
- AIFM3 | c.402C>A p.C134* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV58999600; called by muse, mutect2, varscan2
- AIRE | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52397249; called by muse, mutect2, varscan2
- AKAP13 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs576412136; called by muse, mutect2, varscan2
- AKAP13 | c.3520G>A p.A1174T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs147919379; called by muse, mutect2, varscan2
- AKAP17A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as rs1302375114, COSV58308904; called by muse, varscan2
- AKAP6 | c.4082G>A p.G1361D | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.388); catalogued as rs1405601715; called by muse, mutect2, varscan2
- AKAP9 | c.5801G>A p.R1934H (on ENST00000359028; = p.R1902H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as rs369082700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.9139C>T p.R3047* (on ENST00000359028; = p.R3023* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 138/242 reads (57%) | catalogued as rs773435639, COSV62339561; called by muse, mutect2, varscan2
- AKR1A1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1489844519, COSV61087998; called by muse, mutect2, varscan2
- AKR1B10 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs767733590; called by muse, mutect2, varscan2
- AKR1C2 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV66334292; called by muse, mutect2, varscan2
- AKR1E2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs748631440, COSV53629928; called by muse, mutect2, varscan2
- AKR7A2 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52515697; called by muse, mutect2, varscan2
- AKR7A3 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs766929078; called by muse, mutect2, varscan2
- AKT1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); catalogued as rs774360915; called by muse, mutect2, varscan2
- ALAD | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as rs1218961451; called by muse, varscan2
- ALAS1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs767065228; called by muse, mutect2, varscan2
- ALB | c.1652C>T p.T551I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.299); catalogued as rs149079814; called by muse, mutect2, varscan2
- ALCAM | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs577619201; called by muse, mutect2, varscan2
- ALDH1B1 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs143477600; called by muse, mutect2, varscan2
- ALDH1L2 | c.2602A>G p.M868V | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs775594595; called by muse, mutect2, varscan2
- ALDH4A1 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.871); catalogued as rs751983201; called by muse, mutect2, varscan2
- ALDH5A1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs772361710, COSV100708811; called by muse, mutect2, varscan2
- ALDH7A1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs746212816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG10B | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.245); catalogued as COSV58144500; called by muse, mutect2, varscan2
- ALG10B | c.1329C>A p.C443* | Nonsense Mutation (SNP) | VAF 76/199 reads (38%) | catalogued as COSV100439830; called by muse, mutect2, varscan2
- ALG12 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | PolyPhen benign (0.006); catalogued as COSV100427032; called by muse, mutect2, varscan2
- ALG13 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99322109; called by muse, mutect2, varscan2
- ALG6 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV54763161; called by muse, mutect2, varscan2
- ALK | c.1705G>A p.V569M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs754971913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH1 | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as COSV99380777; called by muse, mutect2, varscan2
- ALKBH4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs564272056; called by muse, mutect2, varscan2
- ALMS1 | c.3425C>T p.T1142I | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs570699297, COSV52506132; called by muse, varscan2
- ALMS1 | c.8328G>A p.M2776I | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs775982049, COSV100040998; called by muse, mutect2, varscan2
- ALMS1 | c.8882C>T p.P2961L | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs781477502; ClinVar: uncertain significance; called by muse, varscan2
- ALPK3 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as rs199599837, COSV51933639; called by muse, mutect2, varscan2
- ALPK3 | c.4409A>G p.Q1470R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs765694865; called by mutect2, varscan2
- ALS2CL | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs761419445; called by mutect2, varscan2
- ALS2CL | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs117431144; called by muse, mutect2, varscan2
- AMDHD1 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV57137668; called by muse, mutect2, varscan2
- AMER1 | c.2911G>A p.G971S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.081); catalogued as rs371014578, COSV57671543; called by muse, varscan2
- AMER1 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs765543269; called by muse, varscan2
- AMER1 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57670846; called by muse, varscan2
- AMMECR1L | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV55761668, COSV99761180; called by muse, mutect2, varscan2
- AMPD1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as rs369685849; called by mutect2, varscan2
- AMPD3 | c.1204C>T p.R402C (on ENST00000396553 / NM_001025389.2; = p.R411C on NM_000480.3) | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766280048, CM940057; called by muse, mutect2, varscan2
- ANAPC5 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs115934510, COSV55841788; called by muse, mutect2, varscan2
- ANG | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749308574, COSV59011466; called by muse, mutect2, varscan2
- ANGPTL6 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs984761722; called by muse, mutect2, varscan2
- ANK2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.436); catalogued as rs901601971, COSV52148836, COSV52150935; called by muse, mutect2, varscan2
- ANK2 | c.11539G>A p.V3847I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as rs1448123780, COSV52176744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.9179C>A p.S3060Y | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs376855070; called by muse, mutect2, varscan2
- ANK3 | c.2413C>T p.R805C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324042095, COSV55065903; called by muse, mutect2, varscan2
- ANKDD1A | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as rs758305337; called by muse, mutect2, varscan2
- ANKEF1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766863397, COSV65692332; called by mutect2, varscan2
- ANKEF1 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs201360021, COSV65693064; called by muse, mutect2, varscan2
- ANKFN1 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752632877; called by muse, mutect2, varscan2
- ANKFY1 | c.2995G>A p.A999T (on ENST00000341657 / NM_001330063.2; = p.A1000T on NM_016376.5) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747203838, COSV58918399; called by muse, mutect2, varscan2
- ANKLE2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1483776717; called by muse, mutect2, varscan2
- ANKMY2 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs1478992649; called by mutect2, varscan2
- ANKRD11 | c.5756C>T p.A1919V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs773848887, COSV56370607; called by muse, mutect2, varscan2
- ANKRD11 | c.2748C>A p.N916K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV56361784; called by muse, mutect2, varscan2
- ANKRD11 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV56367379; called by muse, mutect2, varscan2
- ANKRD12 | c.2125C>T p.L709F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as COSV50862507; called by muse, mutect2, varscan2
- ANKRD13A | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs746448236; called by muse, mutect2, varscan2
- ANKRD13A | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55675585; called by muse, mutect2
- ANKRD13B | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1245858634; called by muse, mutect2, varscan2
- ANKRD13B | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100801405; called by muse, mutect2, varscan2
- ANKRD40 | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99560577; called by muse, mutect2, varscan2
- ANKRD6 | c.1718G>A p.R573K (on ENST00000339746 / NM_001242809.2; = p.R568K on NM_014942.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1563181371; called by muse, mutect2, varscan2
- ANKS6 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs1424021622; called by muse, mutect2, varscan2
- ANKS6 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs996243039, COSV62052230; called by muse, mutect2
- ANKS6 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs201704559; called by muse, mutect2, varscan2
- ANLN | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559978701; called by muse, mutect2, varscan2
- ANO2 | c.1645G>A p.V549I (on ENST00000356134 / NM_001278597.3; = p.V553I on NM_001278596.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs774365666; called by muse, mutect2, varscan2
- ANO4 | c.226G>A p.D76N (on ENST00000392977 / NM_001286615.2; = p.D41N on NM_178826.4) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs555894245; called by muse, mutect2, varscan2
- ANO5 | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV61085649; called by muse, mutect2, varscan2
- ANO9 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV60451133; called by muse, mutect2, varscan2
- ANP32D | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.053); catalogued as COSV56980006; called by muse, mutect2, varscan2
- ANPEP | c.2831C>T p.T944M | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376373199; called by muse, mutect2, varscan2
- ANXA10 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 45/134 reads (34%) | catalogued as rs1192134579, COSV100829098; called by muse, mutect2, varscan2
- ANXA3 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376086128; called by muse, mutect2, varscan2
- ANXA6 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1177861653, COSV62905807; called by muse, varscan2
- AOPEP | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs759309223; called by mutect2, varscan2
- AP002512.3 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs975247035; called by muse, mutect2, varscan2
- AP1B1 | c.2812C>T p.H938Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1253952718; called by muse, mutect2, varscan2
- AP1G2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs566425276, COSV55337743; called by muse, mutect2, varscan2
- AP2A1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1363305347, COSV62820203; called by muse, mutect2, varscan2
- AP2A2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs549459789; called by muse, mutect2, varscan2
- AP2B1 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99251793; called by muse, mutect2, varscan2
- AP3D1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777985586; called by muse, mutect2, varscan2
- APBA2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV67104459; called by muse, mutect2, varscan2
- APBB1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs765361536, COSV54977639; called by muse, mutect2, varscan2
- APBB1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 25/401 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54978999; called by muse, mutect2
- APBB1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as rs749187223, COSV54977232; called by muse, mutect2, varscan2
- APBB1IP | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1210706920; called by muse, mutect2, varscan2
- APBB2 | c.2036G>A p.R679H (on ENST00000295974 / NM_001166050.2; = p.R680H on NM_004307.2) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs371307741; called by muse, mutect2, varscan2
- APEH | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV56531965; called by muse, mutect2, varscan2
- APLP2 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs372035411; called by muse, mutect2, varscan2
- APMAP | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.424); catalogued as COSV54172311; called by muse, mutect2, varscan2
- APOB | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs776786681, COSV51931087; called by muse, mutect2, varscan2
- APOBEC3G | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs776778876, COSV68470693; called by muse, mutect2, varscan2
- APOD | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781078841; called by muse, mutect2, varscan2
- APOE | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1050106163; called by muse, mutect2, varscan2
- APP | c.995A>G p.D332G | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs773998162; called by muse, mutect2, varscan2
- APPL1 | c.460dup p.R154Kfs*4 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs749401724; called by mutect2, varscan2
- APPL1 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs775644362, COSV55702391; called by muse, varscan2
- AQP1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs556371635, COSV61266908; called by muse, mutect2, varscan2
- AQP5 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs754419280, COSV99527462; called by muse, mutect2, varscan2
- AR | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV65955458; called by muse, mutect2, varscan2
- ARFGEF3 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs754312669; called by muse, mutect2, varscan2
- ARGFX | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as rs548796906, COSV57681504; called by muse, mutect2, varscan2
- ARHGAP12 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs1195703426; called by muse, mutect2, varscan2
- ARHGAP15 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV54510235; called by muse, mutect2, varscan2
- ARHGAP20 | c.3304T>C p.S1102P | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as rs1277878874; called by muse, mutect2, varscan2
- ARHGAP20 | c.630+1G>A p.X210_splice | Splice Site (SNP) | VAF 34/84 reads (40%) | catalogued as rs1449319024, COSV52814832; called by muse, mutect2, varscan2
- ARHGAP21 | c.3309G>T p.E1103D | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV57606829; called by muse, varscan2
- ARHGAP29 | c.2954A>C p.K985T | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs760656559; called by muse, mutect2, varscan2
- ARHGAP30 | c.2244dup p.E749Rfs*3 | Frame Shift Ins (INS) | VAF 68/264 reads (26%) | catalogued as rs755222428; called by mutect2, pindel, varscan2
- ARHGAP32 | c.5279G>A p.R1760H (on ENST00000310343 / NM_001378025.1; = p.R1411H on NM_014715.4) | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs550791905, COSV59845479; called by muse, mutect2, varscan2
- ARHGAP4 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.099); catalogued as rs1557102837; called by muse, mutect2
- ARHGAP45 | c.2056G>A p.V686M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs370399922; called by muse, mutect2
- ARHGAP9 | c.1846C>T p.R616W (on ENST00000393797 / NM_001319850.2; = p.R597W on NM_032496.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs747924330; called by muse, mutect2, varscan2
- ARHGEF1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs782282800; called by muse, varscan2
- ARHGEF10L | c.3271C>T p.P1091S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); catalogued as rs768413335; called by muse, mutect2, varscan2
- ARHGEF10L | c.3611G>A p.S1204N | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.24); catalogued as COSV99391962; called by muse, mutect2, varscan2
- ARHGEF11 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1420230862, COSV59356893; called by muse, mutect2, varscan2
- ARHGEF12 | c.3455G>A p.G1152E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as rs528014894; called by mutect2, varscan2
- ARHGEF16 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.067); catalogued as rs749891677; called by muse, mutect2, varscan2
- ARHGEF17 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs575665175, COSV99736247; called by mutect2, varscan2
- ARHGEF17 | c.4282G>A p.A1428T | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs756558176; called by muse, varscan2
- ARHGEF18 | c.664C>T p.R222W (on ENST00000359920 / NM_001130955.2; = p.R118W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769110620; called by muse, mutect2, varscan2
- ARHGEF2 | c.1082G>A p.R361H (on ENST00000361247 / NM_001162383.2; = p.R333H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58114766; called by muse, mutect2, varscan2
- ARHGEF2 | c.932G>A p.R311Q (on ENST00000361247 / NM_001162383.2; = p.R283Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs755710866; called by muse, mutect2, varscan2
- ARHGEF37 | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV61369600; called by muse, varscan2
- ARHGEF6 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV99166416; called by muse, mutect2, varscan2
- ARHGEF9 | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99491181; called by muse, mutect2, varscan2
- ARID1A | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV61378997; called by muse, mutect2, varscan2
- ARID1A | c.5269G>T p.A1757S | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100250362; called by muse, mutect2, varscan2
- ARID1A | c.5938C>T p.R1980C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780084398, COSV61381921; called by muse, varscan2
- ARID1B | c.1893G>A p.M631I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as rs142897795, COSV99034243; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARID1B | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs377588212; called by muse, mutect2, varscan2
- ARID1B | c.6470C>T p.A2157V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs756720427; called by muse, mutect2, varscan2
- ARID2 | c.3049C>T p.H1017Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.039); catalogued as COSV57603320; called by muse, mutect2, varscan2
- ARID2 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1300029603; called by muse, mutect2, varscan2
- ARID4A | c.2276A>G p.K759R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs1274664036; called by muse, mutect2
- ARL15 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs1561228692, COSV101544765; called by muse, mutect2, varscan2
- ARMC12 | c.790G>A p.A264T (on ENST00000373866 / NM_001286574.2; = p.A291T on NM_145028.5) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs200490512; called by muse, mutect2, varscan2
- ARMC4 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs1426540917; called by muse, mutect2, varscan2
- ARMC5 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs747989024, COSV99192306; called by muse, mutect2, varscan2
- ARMC8 | c.1201C>T p.R401W (on ENST00000469044 / NM_001363941.2; = p.R387W on NM_015396.6) | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1307854914, COSV58620603; called by muse, mutect2, varscan2
- ARMH3 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as rs1383116155, COSV64232782; called by muse, mutect2, varscan2
- ARMT1 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as rs560894715, COSV100939733; called by muse, mutect2, varscan2
- ARPP21 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51809291; called by muse, mutect2, varscan2
- ARRB1 | c.429C>A p.D143E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as rs1157947212; called by muse, mutect2
- ARSA | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs770694856; called by muse, mutect2, varscan2
- ARSD | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1300736970; called by muse, mutect2
- ARSH | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66963475; called by muse, mutect2
- ARVCF | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs1219646019; called by muse, mutect2, varscan2
- ASAH2 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260848768; called by muse, mutect2, varscan2
- ASB12 | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV62857387; called by muse, mutect2, varscan2
- ASB13 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs149846489; called by muse, mutect2, varscan2
- ASB6 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs1462160370; called by muse, mutect2, varscan2
- ASH1L | c.8402G>A p.R2801H (on ENST00000368346 / NM_001366177.2; = p.R2796H on NM_018489.3) | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs369654728; called by muse, mutect2, varscan2
- ASH2L | c.415T>C p.F139L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51699944; called by muse, varscan2
- ASIC3 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as rs62001891, COSV52501790; called by muse, mutect2, varscan2
- ASNSD1 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53622915, COSV53623335; called by muse, mutect2, varscan2
- ASPM | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs749600804, COSV99659426; called by muse, mutect2, varscan2
- ASTN1 | c.3730C>T p.R1244W | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs747846402, COSV62496573; called by muse, mutect2, varscan2
- ASXL3 | c.5737G>A p.V1913I | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as COSV99327030; called by muse, mutect2, varscan2
- ATAD5 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs899243141, COSV58978549; called by muse, mutect2, varscan2
- ATAD5 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs752880274; called by muse, mutect2, varscan2
- ATF5 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61312490; called by muse, mutect2, varscan2
- ATG101 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1267727060; called by muse, mutect2, varscan2
- ATG2A | c.2908G>A p.V970I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1312646826; called by muse, mutect2, varscan2
- ATG7 | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV61615144; called by muse, varscan2
- ATG7 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV61615019; called by muse, varscan2
- ATG9A | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.497); catalogued as rs770289897, COSV60132266; called by muse, mutect2, varscan2
- ATM | c.1619G>A p.C540Y | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53784502; called by muse, mutect2, varscan2
- ATM | c.4853G>A p.R1618Q | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs765759912; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATP10B | c.3127C>T p.R1043* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as rs748360139, COSV59142938; called by mutect2, varscan2
- ATP10D | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs201342683; called by muse, varscan2
- ATP10D | c.1499G>A p.S500N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV56713280; called by muse, varscan2
- ATP11A | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs372464773, COSV52111737; called by muse, mutect2, varscan2
- ATP12A | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs767088904; called by muse, mutect2, varscan2
- ATP13A1 | c.489C>T p.G163= | Splice Region (SNP) | VAF 12/25 reads (48%) | catalogued as rs376339960; called by muse, mutect2, varscan2
- ATP1A1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs139745455; called by muse, varscan2
- ATP1A2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs748084473; called by muse, mutect2, varscan2
- ATP2A2 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV57875895; called by muse, mutect2, varscan2
- ATP2B2 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 114/295 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762962570; called by muse, mutect2, varscan2
- ATP2C2 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs373471007; called by muse, varscan2
- ATP5F1B | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV56262233; called by muse, mutect2, varscan2
- ATP6V0C | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs1321416008; called by muse, mutect2, varscan2
- ATP6V0D2 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as rs759946535, COSV53415469; called by muse, mutect2, varscan2
- ATP6V1B1 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.524); catalogued as rs1553416800; called by muse, mutect2, varscan2
- ATP6V1E2 | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60576353; called by muse, mutect2, varscan2
- ATP7A | c.1510G>T p.A504S | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.559); catalogued as COSV58451154; called by muse, mutect2, varscan2
- ATP8A2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99682415; called by muse, mutect2, varscan2
- ATP9A | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473801768; called by muse, mutect2, varscan2
- ATPSCKMT | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.575); catalogued as rs781773524, COSV54726454; called by muse, mutect2, varscan2
- ATR | c.7792C>T p.R2598* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV53817531; called by muse, mutect2, varscan2
- ATRNL1 | c.2818+1G>A p.X940_splice | Splice Site (SNP) | VAF 33/101 reads (33%) | catalogued as rs370774879, COSV58072319; called by muse, mutect2, varscan2
- ATRX | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs782405215; called by muse, mutect2, varscan2
- ATXN7L2 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs749111871; called by muse, varscan2
- AUTS2 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV61432444; called by muse, mutect2, varscan2
- AVIL | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as rs374415947, COSV57682514; called by muse, varscan2
- AVPR1B | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782179665; called by muse, mutect2, varscan2
- AVPR2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs781891175, COSV61686481; called by muse, varscan2
- AXIN1 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as rs377025983; called by muse, mutect2, varscan2
- B3GALT2 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as rs201042990, COSV66464429; called by muse, mutect2, varscan2
- B3GALT5 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs372607334; called by muse, mutect2, varscan2
- B3GNT4 | c.679A>G p.N227D | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57336961; called by muse, mutect2, varscan2
- B3GNT5 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs764711401; called by muse, mutect2, varscan2
- B4GALNT3 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745826262; called by muse, mutect2, varscan2
- B4GALNT4 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs764011918, COSV57323358; called by muse, mutect2, varscan2
- B4GALT6 | c.1074A>C p.K358N | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99380224; called by muse, varscan2
- BACE2 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs778102614; called by muse, mutect2, varscan2
- BACE2 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs757902823, COSV57744313; called by muse, mutect2, varscan2
- BAG6 | c.1673C>A p.P558H (on ENST00000676571; = p.P511H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs762620041; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 20/79 reads (25%) | catalogued as rs745882580; called by mutect2, varscan2
- BAIAP2 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58333980; called by muse, mutect2, varscan2
- BANP | c.1043C>T p.P348L (on ENST00000286122; = p.P317L on NM_017869.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as rs754021644, COSV53737190; called by muse, mutect2, varscan2
- BAZ1B | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 195/366 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781960879; called by muse, mutect2, varscan2
- BAZ2B | c.4103C>T p.A1368V | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs764609647, COSV58609868; called by muse, mutect2, varscan2
- BBS10 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV67913459; called by muse, mutect2, varscan2
- BBS5 | c.356G>T p.R119I | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54753209; called by muse, mutect2, varscan2
- BBS7 | c.1525C>A p.L509M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs768395699; called by mutect2, varscan2
- BCAM | c.1640C>A p.A547D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200219071; called by muse, varscan2
- BCAR3 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.418); catalogued as rs1265341111; called by muse, varscan2
- BCAR3 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1252925845, COSV53071743; called by muse, mutect2, varscan2
- BCAS3 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as rs751009642, COSV66774059; called by muse, mutect2, varscan2
- BCAS3 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs201197944; called by muse, mutect2, varscan2
- BCDIN3D | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV100445587; called by muse, mutect2, varscan2
- BCL2L10 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 112/271 reads (41%) | catalogued as rs756991240, COSV53064528; called by muse, mutect2, varscan2
- BCORL1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs749188963, COSV54400940; called by muse, mutect2, varscan2
- BCR | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as rs368824679; called by muse, mutect2, varscan2
- BEND2 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 169/417 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs146293624; called by muse, mutect2, varscan2
- BEND2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.044); catalogued as rs1246587529; called by muse, mutect2, varscan2
- BEND3 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200333807; called by muse, mutect2, varscan2
- BFSP1 | c.1880C>A p.S627Y | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64899579; called by muse, mutect2, varscan2
- BFSP1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs754085071; called by muse, mutect2, varscan2
- BFSP1 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748876889; called by muse, mutect2, varscan2
- BFSP2 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 10/117 reads (9%) | catalogued as rs1224719314, COSV56591649; called by muse, mutect2
- BICD1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV55685869; called by muse, mutect2, varscan2
- BICD2 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs753891194, COSV63551182; called by muse, mutect2, varscan2
- BICRAL | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs138499464; called by muse, mutect2, varscan2
- BIN1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs762897872, COSV52116138; called by muse, mutect2, varscan2
- BIN3 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs370278385, COSV99374137; called by mutect2, varscan2
- BIRC6 | c.10787C>T p.S3596F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.708); catalogued as COSV101428123; called by muse, mutect2, varscan2
- BIRC7 | c.787G>A p.V263I (on ENST00000217169 / NM_139317.3; = p.V245I on NM_022161.4) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1211741916, COSV53903059; called by muse, mutect2, varscan2
- BLCAP | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99289914; called by muse, mutect2, varscan2
- BLM | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs148545569; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- BLNK | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 37/94 reads (39%) | catalogued as rs1554896956; called by muse, varscan2
- BLNK | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782275274; called by muse, varscan2
- BLVRA | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs138692014; called by muse, mutect2, varscan2
- BMP1 | c.1798G>A p.G600S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs371549770; called by muse, mutect2, varscan2
- BMP10 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs778579679, COSV99770295; called by muse, mutect2, varscan2
- BMP3 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99261708; called by muse, mutect2, varscan2
- BMP5 | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as rs780354171; called by mutect2, varscan2
- BMP5 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.895); catalogued as COSV63702143; called by muse, mutect2, varscan2
- BMP5 | c.133A>G p.N45D | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); catalogued as rs749317599, COSV100895878; called by muse, mutect2, varscan2
- BMPER | c.1743C>T p.Y581= | Splice Region (SNP) | VAF 19/58 reads (33%) | catalogued as rs373141339; called by muse, mutect2, varscan2
- BMX | c.156A>T p.K52N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59591836; called by muse, mutect2
- BOC | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs148702312; called by muse, mutect2, varscan2
- BORA | c.1360G>A p.D454N (on ENST00000613797; = p.D379N on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs376265700; called by muse, mutect2, varscan2
- BPI | c.205T>C p.S69P (on ENST00000262865; = p.S65P on NM_001725.3) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV53408790; called by muse, mutect2, varscan2
- BPI | c.1324A>G p.I442V (on ENST00000262865; = p.I438V on NM_001725.3) | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1431103033; called by muse, mutect2, varscan2
- BPIFB4 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs145491929, COSV64952456, COSV99070674; called by muse, mutect2, varscan2
- BRAF | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1461617552, COSV56074414; ClinVar: uncertain significance; called by muse, varscan2
- BRAT1 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs774062331; ClinVar: uncertain significance; called by muse, varscan2
- BRCA2 | c.4456G>A p.V1486I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as CD994642; called by muse, mutect2, varscan2
- BRD2 | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771034602; called by muse, mutect2, varscan2
- BRF1 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.143); catalogued as rs369638144; called by muse, mutect2, varscan2
- BRICD5 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs376322862; called by muse, varscan2
- BRINP2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 113/263 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as rs780568954, COSV64175922; called by muse, mutect2, varscan2
- BRINP3 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as rs1176677978, COSV100819595; called by muse, varscan2
- BRPF1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1007331876; called by muse, mutect2, varscan2
- BRPF1 | c.3634G>A p.D1212N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as rs771709410; called by muse, mutect2, varscan2
- BRPF3 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as rs779537519; called by muse, mutect2, varscan2
- BRPF3 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs774981200; called by muse, mutect2, varscan2
- BRWD1 | c.3721G>A p.E1241K | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60896299; called by muse, mutect2, varscan2
- BRWD1 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs778720112; called by muse, mutect2, varscan2
- BRWD3 | c.5317G>T p.D1773Y | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1244461321; called by muse, varscan2
- BRWD3 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs777374143; called by muse, mutect2, varscan2
- BSDC1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1407537332; called by muse, mutect2, varscan2
- BSPRY | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs376015885; called by muse, mutect2, varscan2
- BTAF1 | c.5306A>G p.K1769R | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs201415370; called by muse, mutect2, varscan2
- BTBD17 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs189934812, COSV100945388; called by muse, mutect2, varscan2
- BTG4 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100604563; called by muse, mutect2, varscan2
- BTN2A1 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV57003163; called by muse, mutect2, varscan2
- BTN2A2 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs375285642; called by muse, mutect2, varscan2
- BTN3A3 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.178); catalogued as rs746357036, COSV99765019; called by muse, mutect2, varscan2
- BUD13 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437345814; called by muse, mutect2
- C11orf49 | c.279C>T p.G93= | Splice Region (SNP) | VAF 27/58 reads (47%) | catalogued as rs760935932, COSV53565125; called by muse, mutect2, varscan2
- C14orf28 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as rs749310294, COSV57333841; called by muse, varscan2
- C14orf93 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.009); catalogued as rs759076674; called by muse, mutect2, varscan2
- C16orf87 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs1012743684, COSV99587625; called by muse, mutect2, varscan2
- C19orf54 | c.661T>G p.F221V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV54573998; called by muse, mutect2, varscan2
- C19orf57 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as COSV60968667; called by muse, mutect2, varscan2
- C1QA | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1205578881, COSV65889417; called by muse, mutect2, varscan2
- C1QA | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs376612598; called by muse, mutect2, varscan2
- C1QTNF6 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs748662192, COSV55396317, COSV55397329; called by muse, mutect2
- C1RL | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.94); catalogued as rs1365556157; called by muse, mutect2, varscan2
- C1orf112 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV53680954; called by muse, mutect2
- C1orf158 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1268933305; called by muse, mutect2, varscan2
- C1orf162 | c.202+1G>A p.X68_splice | Splice Site (SNP) | VAF 28/66 reads (42%) | catalogued as rs375173716; called by muse, mutect2, varscan2
- C1orf210 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV70682501; called by muse, mutect2, varscan2
- C1orf94 | c.679C>T p.R227C (on ENST00000488417 / NM_001134734.2; = p.R37C on NM_032884.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as rs1472847493, COSV64913805; called by muse, mutect2
- C1orf94 | c.1784G>A p.G595D (on ENST00000488417 / NM_001134734.2; = p.G405D on NM_032884.5) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs754716272, COSV64914862; called by muse, mutect2, varscan2
- C20orf96 | c.824C>T p.A275V (on ENST00000360321 / NM_153269.3; = p.A274V on NM_080571.1) | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759366822, COSV64403346; called by muse, mutect2, varscan2
- C2CD3 | c.3655C>T p.R1219W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs764341376, COSV100487497; called by muse, mutect2, varscan2
- C2CD5 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61725262; called by muse, mutect2
- C2CD6 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV53799937; called by muse, varscan2
- C2orf16 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.82); catalogued as COSV101284419; called by muse, mutect2, varscan2
- C2orf16 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as COSV68646979; called by muse, mutect2, varscan2
- C2orf16 | c.2813C>A p.P938H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100821173; called by muse, mutect2, varscan2
- C3 | c.3646+1G>A p.X1216_splice | Splice Site (SNP) | VAF 111/301 reads (37%) | catalogued as rs113847049; called by muse, mutect2, varscan2
- C3 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55572450, COSV99836796; called by muse, varscan2
- C3AR1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756745490, COSV50817573; called by muse, mutect2, varscan2
- C3orf22 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as rs373190783; called by muse, mutect2, varscan2
- C5 | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.18); catalogued as rs764555226; called by muse, mutect2, varscan2
- C6orf89 | c.196G>A p.A66T (on ENST00000373685; = p.A73T on NM_152734.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs755983658; called by muse, mutect2, varscan2
- C8B | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.255); catalogued as COSV64779576; called by muse, mutect2, varscan2
- C8B | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291784285; called by muse, mutect2, varscan2
- C8orf76 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs149988027; called by muse, mutect2, varscan2
- C9orf131 | c.2993G>T p.S998I | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as COSV100398315; called by muse, mutect2, varscan2
- C9orf50 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1017694849, COSV100992358; called by muse, mutect2, varscan2
- CAB39 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs575964287, COSV51477979; called by muse, mutect2, varscan2
- CABIN1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs762448140; called by muse, mutect2, varscan2
- CABIN1 | c.1682G>A p.G561D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1381175589; called by muse, mutect2, varscan2
- CABIN1 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756557911; called by muse, mutect2, varscan2
- CABP2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320588437; called by muse, varscan2
- CACNA1B | c.872A>C p.N291T | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53131252; called by muse, mutect2, varscan2
- CACNA1B | c.4397C>T p.T1466I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs1382604588; called by muse, mutect2, varscan2
- CACNA1B | c.5726G>A p.R1909Q | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.056); catalogued as rs200511648; called by muse, mutect2, varscan2
- CACNA1D | c.1511G>A p.R504H (on ENST00000350061 / NM_001128840.3; = p.R524H on NM_000720.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.043); catalogued as COSV55449352; called by muse, mutect2, varscan2
- CACNA1F | c.5264G>A p.R1755Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1557105073; called by muse, mutect2
- CACNA1G | c.1997G>A p.S666N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs757313737; called by muse, mutect2, varscan2
- CACNA1H | c.4189G>A p.V1397M | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186328765, COSV61991376; called by muse, varscan2
- CACNA1H | c.4660G>A p.V1554M | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1017716807, COSV61982951; called by muse, mutect2, varscan2
- CACNA1I | c.1995G>A p.P665= | Splice Region (SNP) | VAF 36/126 reads (29%) | catalogued as rs1344867036; called by muse, mutect2, varscan2
- CACNA1S | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs761248676, COSV62936590; called by muse, mutect2, varscan2
- CACNA2D1 | c.3157C>T p.R1053* (on ENST00000356253 / NM_001366867.1; = p.R1041* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 62/116 reads (53%) | catalogued as rs752471498, COSV62376523; called by muse, mutect2, varscan2
- CACNA2D2 | c.993G>A p.S331= | Splice Region (SNP) | VAF 12/36 reads (33%) | catalogued as rs780661542, COSV56568964; called by muse, varscan2
- CACNB2 | c.1869G>T p.K623N (on ENST00000324631 / NM_201596.3; = p.K568N on NM_000724.4) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.432); catalogued as COSV56651162; called by muse, varscan2
- CACNG1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs760216442, COSV56826298, COSV56827091; called by muse, mutect2, varscan2
- CACNG2 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55632327; called by muse, mutect2, varscan2
- CACNG7 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs751560841, COSV55816777; called by muse, mutect2, varscan2
- CAD | c.3340G>A p.A1114T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1350143785; called by muse, mutect2, varscan2
- CADM1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.683); catalogued as rs986045773, COSV59017228; called by muse, varscan2
- CADPS | c.3961C>T p.R1321C | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1192160113, COSV51899718; called by muse, varscan2
- CALCB | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773988089, COSV60834345; called by muse, mutect2, varscan2
- CALD1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs145963001; called by muse, varscan2
- CALD1 | c.1855C>T p.R619C (on ENST00000361675 / NM_033138.4; = p.R364C on NM_004342.7) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs370580506; called by muse, mutect2, varscan2
- CALD1 | c.2125G>A p.V709I (on ENST00000361675 / NM_033138.4; = p.V454I on NM_004342.7) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.63); catalogued as rs960544244; called by muse, mutect2
- CALR | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs758904907; called by muse, mutect2, varscan2
- CALU | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147388270; called by muse, mutect2, varscan2
- CAMK2A | c.1339G>A p.A447T (on ENST00000348628 / NM_171825.2; = p.A458T on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs748774194, COSV100652046; called by muse, mutect2, varscan2
- CAMK2G | c.1073C>T p.A358V (on ENST00000423381 / NM_001367518.1; = p.A368V on NM_172170.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as rs994514423, COSV59483840; called by muse, mutect2, varscan2
- CAMK4 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99999901; called by muse, mutect2, varscan2
- CAMKV | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777179632, COSV56555844; called by muse, mutect2, varscan2
- CAMSAP1 | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs765811813, COSV56724521; called by muse, mutect2, varscan2
- CAMSAP2 | c.689G>A p.R230Q (on ENST00000236925 / NM_001297707.2; = p.R219Q on NM_203459.3) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1460540960; called by muse, mutect2, varscan2
- CAMSAP3 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs201644239; called by muse, varscan2
- CANT1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as rs1316078773; called by muse, mutect2, varscan2
- CAPN10 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs758418220; called by muse, mutect2, varscan2
- CAPN11 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs373070433, COSV101291935; called by muse, mutect2, varscan2
- CAPN13 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs374855001; called by muse, mutect2, varscan2
- CAPN13 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs769225286, COSV54428691; called by muse, mutect2, varscan2
- CAPN6 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 188/455 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs780015974, COSV60695154, COSV60697937; called by muse, mutect2, varscan2
- CAPSL | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs779689546, COSV68437345, COSV99081204; called by muse, varscan2
- CAPSL | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368551299, COSV68438743; called by muse, varscan2
- CARD6 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as rs771494999, COSV54564783; called by muse, mutect2, varscan2
- CASD1 | c.1632C>T p.N544= | Splice Region (SNP) | VAF 23/40 reads (58%) | catalogued as rs376448411; called by muse, mutect2, varscan2
- CASP1 | c.1174G>A p.V392M (on ENST00000436863 / NM_033292.4; = p.V371M on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.202); catalogued as COSV52828913; called by muse, mutect2, varscan2
- CASP5 | c.533dup p.N178Kfs*3 | Frame Shift Ins (INS) | VAF 24/130 reads (18%) | catalogued as rs765105588; called by mutect2, varscan2
- CASQ1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs773804780, COSV63624361; called by muse, mutect2, varscan2
- CASQ2 | c.737+1G>T p.X246_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as CS117809; called by muse, varscan2
- CAT | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs201903015; called by muse, mutect2, varscan2
- CAVIN1 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100824630; called by muse, mutect2, varscan2
- CBFA2T2 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs781709547, COSV100656481; called by muse, mutect2, varscan2
- CBFA2T3 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.096); catalogued as rs746944067, COSV51923370; called by muse, mutect2, varscan2
- CBLL1 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | catalogued as rs1362212731, COSV56029919; called by muse, mutect2, varscan2
- CBLN3 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52158641; called by muse, varscan2
- CBS | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1301672360; ClinVar: uncertain significance; called by muse, mutect2
- CBX2 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs141814853; called by muse, mutect2
- CBX4 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1220857927; called by muse, varscan2
- CBX4 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1225130408; called by muse, mutect2, varscan2
- CBX6 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1310524692; called by muse, varscan2
- CBY2 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs775733198, COSV100137936; called by muse, mutect2, varscan2
- CC2D2B | c.22-1G>T p.X8_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100729571; called by muse, mutect2, varscan2
- CCDC105 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs1229678026; called by muse, mutect2, varscan2
- CCDC112 | c.1288A>G p.I430V | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.488); catalogued as rs1321338356; called by muse, mutect2
- CCDC116 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs762931042, COSV99488925; called by muse, mutect2, varscan2
- CCDC130 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99237526; called by muse, mutect2
- CCDC136 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765936662; called by muse, mutect2, varscan2
- CCDC138 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.287); catalogued as rs1457543526, COSV51709842; called by muse, mutect2, varscan2
- CCDC150 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs775760234; called by muse, varscan2
- CCDC157 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs140264936; called by muse, mutect2, varscan2
- CCDC172 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60937626; called by muse, mutect2, varscan2
- CCDC173 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101352356; called by muse, mutect2, varscan2
- CCDC180 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs377355984; called by muse, mutect2, varscan2
- CCDC189 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1567267790; called by muse, mutect2, varscan2
- CCDC24 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1347551847; called by muse, mutect2, varscan2
- CCDC30 | c.1580G>A p.R527H (on ENST00000340612; = p.R484H on NM_001080850.3) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs933242001; called by muse, mutect2, varscan2
- CCDC40 | c.3397G>A p.A1133T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1219930549, COSV100163040; called by muse, mutect2, varscan2
- CCDC54 | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53758837; called by muse, mutect2, varscan2
- CCDC57 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs573980729; called by muse, mutect2, varscan2
- CCDC65 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748450007; called by muse, mutect2, varscan2
- CCDC74B | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs372914463; called by muse, mutect2, varscan2
- CCDC78 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs373278585; called by muse, varscan2
- CCDC82 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567485; called by muse, mutect2, varscan2
- CCDC82 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs998242113; called by muse, mutect2, varscan2
- CCDC85A | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.196); catalogued as rs769536086; called by muse, mutect2, varscan2
- CCDC88A | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.932); catalogued as COSV99709905; called by muse, mutect2, varscan2
- CCL5 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as rs761483805; called by muse, mutect2, varscan2
- CCNB3 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs781990470, COSV52077131; called by muse, mutect2, varscan2
- CCNH | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56925058, COSV99907100; called by muse, mutect2, varscan2
- CCNL2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs746411827; called by muse, mutect2, varscan2
- CCNQ | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs781948889, COSV52344096; called by muse, mutect2, varscan2
- CCNT2 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs751027006; called by muse, mutect2, varscan2
- CCR9 | c.916G>A p.A306T (on ENST00000357632 / NM_031200.3; = p.A294T on NM_006641.4) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1346189977; called by muse, mutect2, varscan2
- CCT3 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as rs376476578; called by muse, mutect2, varscan2
- CCT7 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs11544996; called by muse, mutect2, varscan2
- CCT8L2 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV63462026; called by muse, mutect2
- CCT8L2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs144320279; called by muse, varscan2
- CCT8L2 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.105); catalogued as COSV63463037; called by muse, varscan2
- CD109 | c.3224dup p.L1075Ffs*4 | Frame Shift Ins (INS) | VAF 15/59 reads (25%) | catalogued as rs35580099; called by mutect2, pindel, varscan2
- CD109 | c.3680G>A p.R1227H | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as rs775503130, COSV54650900, COSV54657900; called by muse, mutect2, varscan2
- CD164 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753764917; called by muse, mutect2, varscan2
- CD180 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56520104; called by muse, mutect2, varscan2
- CD1A | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV56861941; called by muse, mutect2
- CD1B | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs200467928, COSV63803912; called by muse, mutect2, varscan2
- CD1E | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as rs369346814; called by muse, mutect2, varscan2
- CD36 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs368907671, COSV59209648, COSV99987784; called by muse, mutect2, varscan2
- CD3D | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV52676204; called by muse, mutect2, varscan2
- CD4 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV50593871; called by muse, mutect2, varscan2
- CD40LG | c.499G>T p.G167* | Nonsense Mutation (SNP) | VAF 171/429 reads (40%) | catalogued as CM054161, CM094863, CM146437, COSV65698374; called by muse, mutect2, varscan2
- CD44 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53533933; called by muse, mutect2, varscan2
- CD5L | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63822427; called by muse, mutect2, varscan2
- CD7 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as COSV53940190; called by muse, mutect2, varscan2
- CD93 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs144280933; called by mutect2, varscan2
- CD99L2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.88); catalogued as rs782620445; called by muse, varscan2
- CDAN1 | c.1736G>A p.S579N | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); catalogued as rs1168302899; called by muse, varscan2
- CDC14B | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs771989587; called by mutect2, varscan2
- CDC20 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as rs781228317; called by muse, mutect2, varscan2
- CDC23 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs746178873; called by muse, mutect2, varscan2
- CDC37L1 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs745342909; called by muse, mutect2, varscan2
- CDC42BPA | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62013212; called by muse, mutect2, varscan2
- CDC42BPA | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62009056; called by muse, mutect2, varscan2
- CDC42BPB | c.3967C>T p.P1323S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as rs1566843777, COSV63475011; called by muse, mutect2, varscan2
- CDCA7L | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 50/220 reads (23%) | catalogued as COSV60948268; called by muse, mutect2, varscan2
- CDCP1 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as rs1461309974; called by muse, mutect2, varscan2
- CDCP1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs777920511; called by muse, mutect2, varscan2
- CDH1 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1555515869; ClinVar: uncertain significance; called by muse, varscan2
- CDH12 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); catalogued as rs371285182; called by muse, mutect2, varscan2
- CDH18 | c.1238C>A p.T413N | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.333); catalogued as COSV56963328; called by muse, mutect2, varscan2
- CDH19 | c.926A>G p.H309R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1441670386; called by muse, mutect2, varscan2
- CDH2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs140836073; called by muse, mutect2, varscan2
- CDH23 | c.7516C>T p.R2506W | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763511564, COSV56477330; called by muse, mutect2, varscan2
- CDH5 | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV58517236; called by muse, mutect2, varscan2
- CDHR5 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as rs980805505, COSV51563888; called by muse, mutect2, varscan2
- CDK1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 28/262 reads (11%) | catalogued as rs11540347; called by muse, mutect2, varscan2
- CDK20 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as rs761408768, COSV100308180; called by muse, varscan2
- CDK4 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.687); catalogued as rs3211612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKL4 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs370476409, COSV101115440; called by muse, mutect2, varscan2
- CDKL4 | c.363C>T p.N121= | Splice Region (SNP) | VAF 28/62 reads (45%) | catalogued as rs375514414, COSV66508603; called by muse, varscan2
- CDKL5 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1347368640, COSV66110917; called by muse, varscan2
- CDKL5 | c.2899C>T p.L967F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66106610; called by muse, mutect2, varscan2
- CDKN2A | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs370823171; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CDKN2AIP | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235180485; called by muse, mutect2, varscan2
- CDKN2AIP | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs747629501, COSV100187718; called by muse, mutect2, varscan2
- CDON | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs1432443996; called by muse, mutect2, varscan2
- CDX4 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.969); catalogued as rs940984524, COSV100999108; called by muse, mutect2, varscan2
- CDYL | c.551G>A p.R184Q (on ENST00000328908 / NM_001368125.1; = p.R130Q on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs758795798; called by muse, mutect2, varscan2
- CEACAM8 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV54990974, COSV99747576; called by muse, mutect2, varscan2
- CEACAM8 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs775470459, COSV54992144; called by muse, mutect2, varscan2
- CEBPE | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as rs1210780744; called by muse, mutect2, varscan2
- CEBPE | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs200138272; called by muse, mutect2, varscan2
- CEBPZ | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201963398; called by muse, mutect2, varscan2
- CELA1 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV53329079; called by muse, varscan2
- CELA2A | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as COSV62747957; called by muse, mutect2
- CELF1 | c.1411C>T p.R471W (on ENST00000358597 / NM_001376422.1; = p.R467W on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 132/256 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV60113818; called by muse, varscan2
- CELSR1 | c.2528C>T p.T843I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs768226039; called by muse, mutect2, varscan2
- CELSR1 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs760631542; called by muse, varscan2
- CELSR2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs41279702; called by muse, mutect2, varscan2
- CELSR2 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 37/364 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs778686097; called by muse, mutect2
- CELSR2 | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775809950, COSV54778069; called by muse, mutect2, varscan2
- CELSR2 | c.7031G>A p.R2344H | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs570931149, COSV54766092; called by muse, varscan2
- CELSR3 | c.5884C>T p.R1962W | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as rs371994495; called by muse, varscan2
- CELSR3 | c.2611C>T p.R871W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs761826324, COSV50846297; called by muse, mutect2, varscan2
- CEMIP | c.1798-2A>G p.X600_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as rs781695922; called by muse, mutect2, varscan2
- CEMIP | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.404); catalogued as rs760551866, COSV54990479; called by muse, varscan2
- CENPBD1 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs1208741794; called by muse, mutect2, varscan2
- CENPF | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as rs977268028; called by muse, mutect2, varscan2
- CENPF | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756993344, COSV65274085; called by muse, mutect2, varscan2
- CENPF | c.1582+2T>C p.X528_splice | Splice Site (SNP) | VAF 29/74 reads (39%) | catalogued as rs374131527; called by muse, mutect2, varscan2
- CENPH | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs200925138; called by muse, mutect2, varscan2
- CEP126 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756490220, COSV54828818; called by mutect2, varscan2
- CEP126 | c.705+1G>A p.X235_splice | Splice Site (SNP) | VAF 24/106 reads (23%) | catalogued as COSV99681000; called by muse, mutect2, varscan2
- CEP131 | c.2767G>A p.E923K (on ENST00000269392 / NM_001319228.2; = p.E920K on NM_014984.4) | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs577025986, COSV53950529; called by muse, varscan2
- CEP131 | c.2447C>T p.A816V (on ENST00000269392 / NM_001319228.2; = p.A813V on NM_014984.4) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs565745717; called by muse, varscan2
- CEP170B | c.2312G>A p.R771H (on ENST00000453495; = p.R700H on NM_015005.3) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs747921276; called by muse, varscan2
- CEP192 | c.6403G>T p.E2135* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV58070427; called by muse, mutect2, varscan2
- CEP192 | c.6922C>A p.L2308M | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58063752; called by muse, varscan2
- CEP250 | c.6608A>G p.E2203G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV61168231; called by muse, mutect2, varscan2
- CEP250 | c.7196C>T p.A2399V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.997); catalogued as rs1476249680; called by muse, mutect2, varscan2
- CEP290 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV58349378; called by muse, varscan2
- CEP350 | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV62607814; called by muse, mutect2, varscan2
- CEP350 | c.5638C>T p.R1880* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs772463321, COSV62600618; called by mutect2, varscan2
- CERS5 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV58190035, COSV58190237; called by muse, mutect2, varscan2
- CES4A | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765087870; called by muse, mutect2, varscan2
- CES5A | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as rs1395543425; called by muse, mutect2, varscan2
- CFAP221 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV99732813; called by muse, mutect2, varscan2
- CFAP299 | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100811630, COSV63881038; called by muse, mutect2, varscan2
- CFAP43 | c.4250G>A p.R1417K | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1359489149; called by muse, mutect2, varscan2
- CFAP43 | c.3590C>T p.T1197I | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs765211178, COSV63854978; called by muse, mutect2, varscan2
- CFAP52 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs374339508; called by muse, varscan2
- CFAP58 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773079523, COSV63832796; called by muse, mutect2, varscan2
- CFAP69 | c.1625C>A p.S542Y | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750031396; called by muse, mutect2, varscan2
- CFAP74 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758203916; called by muse, mutect2, varscan2
- CFAP91 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201045322, COSV56338931; called by muse, mutect2, varscan2
- CFAP92 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as rs757852747, COSV54049079, COSV99414701; called by muse, varscan2
- CFAP92 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs746384531, COSV54046747; called by muse, varscan2
- CFHR4 | c.1578C>A p.N526K (on ENST00000367416 / NM_001201551.2; = p.N280K on NM_006684.5) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs536482365; called by muse, mutect2, varscan2
- CFLAR | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV58580066, COSV58581331; called by muse, mutect2, varscan2
- CFP | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV55950478; called by muse, mutect2, varscan2
- CFP | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203866191; called by muse, mutect2
- CGNL1 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV99847434; called by muse, mutect2, varscan2
11,960 further variants in this file (8,653 protein-altering or splice-affecting, 3,061 silent, 246 other) are not listed here.
